Somatic mutation profile of tumor specimen TCGA-OU-A5PI-01A (aliquot TCGA-OU-A5PI-01A-12D-A29I-10) from TCGA case TCGA-OU-A5PI, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 53.4 years (19,492 days).
Specimen TCGA-OU-A5PI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64e34171-4d32-43d0-82d4-3e2d1521c481.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OU-A5PI-10A (Blood Derived Normal), aliquot TCGA-OU-A5PI-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f835c36-6dc7-4e74-9907-fb6e770193b1

The open-access MAF lists 28 somatic variants for this specimen: 18 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 9, In Frame Del 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATXN3L | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs1555931850; called by muse, mutect2, varscan2
- HOXA9 | c.704G>C p.R235P | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100604349; called by muse, mutect2, varscan2
- KEAP1 | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 106/454 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.684); catalogued as COSV50260624; called by muse, varscan2
- NLRP9 | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60461569; called by muse, mutect2, varscan2
- PCDH15 | c.1566G>A p.M522I | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.241); catalogued as rs1159351115, COSV57268433; called by muse, mutect2, varscan2
- SVEP1 | c.9377C>T p.P3126L | Missense Mutation (SNP) | VAF 112/232 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376942718; called by muse, mutect2, varscan2
- TTN | c.78707G>A p.R26236H (on ENST00000591111; = p.R18812H on NM_003319.4) | Missense Mutation (SNP) | VAF 50/75 reads (67%) | PolyPhen possibly damaging (0.591); catalogued as rs371345921, COSV60102874; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF474 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV99682297; called by muse, mutect2, varscan2
- ZNF714 | c.1271T>C p.L424P | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1288771724, COSV52509475; called by muse, mutect2, varscan2
- ASPM | c.7245G>C p.Q2415H | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FADD | c.124G>C p.G42R | Missense Mutation (SNP) | VAF 72/110 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRBA1 | c.1846G>C p.E616Q | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LMNB1 | c.97_99del p.K33del | In Frame Del (DEL) | VAF 54/233 reads (23%) | called by mutect2, pindel, varscan2
- NOVA1 | c.1397G>A p.G466D | Missense Mutation (SNP) | VAF 106/256 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PCCA | c.915C>A p.S305R | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHF2 | c.2429_2436del p.C810Yfs*72 | Frame Shift Del (DEL) | VAF 81/220 reads (37%) | called by mutect2, pindel, varscan2
- SERPINA3 | c.757T>C p.Y253H | Missense Mutation (SNP) | VAF 29/346 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.412); called by muse, mutect2
- ZRSR2 | c.205C>G p.Q69E | Missense Mutation (SNP) | VAF 139/392 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ARHGAP36 | c.561A>T p.A187= | Silent (SNP) | VAF 51/122 reads (42%) | called by muse, mutect2, varscan2
- CELA3B | c.69T>C p.S23= | Silent (SNP) | VAF 65/106 reads (61%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.684A>G p.G228= | Silent (SNP) | VAF 62/144 reads (43%) | called by muse, mutect2, varscan2
- CROCC | c.2607T>G p.R869= | Silent (SNP) | VAF 40/78 reads (51%) | catalogued as rs766505719; called by muse, varscan2
- DMRT2 | c.999A>G p.R333= | Silent (SNP) | VAF 54/140 reads (39%) | catalogued as COSV99426096; called by muse, mutect2, varscan2
- FAM219B | c.465G>A p.Q155= | Silent (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- INPP4B | c.351C>T p.V117= | Silent (SNP) | VAF 42/145 reads (29%) | called by muse, mutect2, varscan2
- RANBP17 | c.2268T>A p.V756= | Silent (SNP) | VAF 62/218 reads (28%) | called by muse, mutect2, varscan2
- UBA5 | c.342T>C p.N114= | Silent (SNP) | VAF 44/91 reads (48%) | catalogued as rs1444445994; called by muse, mutect2, varscan2
- PLCB1 | c.3423+11820C>T | Intron (SNP) | VAF 23/86 reads (27%) | catalogued as rs1361878097, COSV62059342; called by muse, mutect2, varscan2
